Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6930, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6930-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 4

Date:

Examination: Histopathological examination

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender:

Material: **Multiple organ resection – segment of the large intestine**

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the hepatic flexure. Diverticula of the descending colon, polyp of the descending colon**
SPECIMEN - cecum, descending, transverse and ascending colon with the greater omentum.

Examination performed on:

Macroscopic description:

A 63 cm length of the large intestine with periintestinal fat tissue sized 71 x 14 x 8 cm, the omentum sized 36 x 14 x 5 cm, a 5.5 cm length of the small intestine, and a 7.7 cm appendix. Cauliflower-shaped tumour sized 5 x 3.2 x 1.1 cm found in the mucosa. The lesion surrounding 90% of the intestine circumference is located 13.2 cm from the proximal incision line, 52 cm from the distal incision line, and 6.5 cm from the Bauhin's valve. Minimum side margin is 4cm. A polyp of 3.2cm diameter outside the tumour in the region of the descending colon. A second polyp of 1.1. diameter removed by 6.8 cm from the first one, a third polyp of 1.2 cm diameter located opposite the second one, 6cm away.

Microscopic description:

Adenocarcinoma mucinosum (G3).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae.

Intestine ends and the appendix clear of neoplastic lesions.

Outside the tumour: Adenomata tubulopapillaria cum dysplasia gradus minoris ad maiorem. Diverticula.

Lymphonodulitis reactiva lymphonodorum (No XX).

Histopathological diagnosis:

Adenocarcinoma mucinosum colli. Mucinous adenocarcinoma of the colon.
(G3, Dukes B, Astler-Coller B2, pT3, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 4d91619b-cd9b-42b4-9910-5e301dcfacdc (TCGA-D5-6930.0A3FA5B6-52B9-481B-A07F-C62FABC32CC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).